Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7680, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7680-01A (Primary Tumor).

Microscopic

Permanent section of frozen section demonstrates mildly hypercellular white matter. The hypercellularity appears due to cells with mildly atypical angular nuclei with out apparent processes. No mitotic figures are seen. There is no microvascular proliferation or necrosis

Addendum

Sections demonstrate a modestly cellular glial neoplasm, a dense glial fibrillary stroma. The tumor cells tend to be modestly clustered and sometimes oriented around vessels but well formed pseudorosettes are not seen. There is no myxoid or microcystic change and no calcifications are present. Nuclei are consistently round with modest atypia. No mitotic figures are seen.

The neoplastic cells are diffusely immunoreactive for GFAP as is the fibrillary background. There is no punctate cytoplasmic staining for EMA, strong evidence against ependymal or subependymal lineage. Neurofilament stain demonstrates a gradation from normally filamentous at the periphery to only rare neurofilament positive axons centrally. Nevertheless, this pattern does suggest an infiltrative process. MIB-1 demonstrates only a very rare positive cell with an estimated labeling index of less than 0.1%. Overall, this immunophenotype confirms the histologic impression of a very low grade but diffusely infiltrating astrocytic neoplasm

Diagnosis

Consistent with well differentiated astrocytoma grade II

Source: NCI Genomic Data Commons file 105916c1-347a-4754-8ba9-b505f292c86c (TCGA-HT-7680.156C9439-4F38-45CB-AB67-D0BE08FA04FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).